TCGA case TCGA-GL-A59R — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78412f82-cc55-43d5-96ca-1d02cf957725

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 79 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 79.5 years (29,046 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC clinical stage: Stage III; AJCC pathologic T: T3c; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 378 days (1.0 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 9; Prcc type: Type 1.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 203 days; Disease response: Tumor Free.
- Days to follow up: 378 days (1.0 years); Disease response: Tumor Free.
- ECOG performance status: 1; Timepoint: Other.

Molecular and laboratory tests
- Leukocytes: Normal.
- Hemoglobin: Low.
- Platelets: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 81 kg; Height: 177 cm; BMI: 25.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-GL-A59R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,050 mg.
  Slide TCGA-GL-A59R-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-GL-A59R-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-GL-A59R-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-GL-A59R-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 330 mg.
  Slide TCGA-GL-A59R-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: Yes; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 378 days; disease-specific survival: no event (censored), 378 days; disease-free interval: no event (censored), 378 days; progression-free interval: no event (censored), 378 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-GL-A59R-01A-11D-A26O-01): tumor purity 1, ploidy 2.13, whole-genome doublings 0.
